Somatic mutation profile of tumor specimen TCGA-AB-2904-03A (aliquot TCGA-AB-2904-03A-01W-0732-08) from TCGA case TCGA-AB-2904, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.3 years (23,833 days).
Specimen TCGA-AB-2904-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c490d40-42e0-428a-9be1-e73b44649886.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2904-11A (Solid Tissue Normal), aliquot TCGA-AB-2904-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26fc5b30-e38e-4fda-adcd-614b3c266fda

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 87/109 reads (80%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRNL1 | c.1005-2A>T p.X335_splice | Splice Site (SNP) | VAF 7/120 reads (6%) | catalogued as rs782074862, COSV61796831; called by muse, mutect2
- BMP6 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs750151436, COSV51667126; called by muse, mutect2, varscan2
- C4BPB | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as rs1426252135, COSV54691747, COSV99700211; called by muse, mutect2, varscan2
- CCDC171 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs772838312, COSV52636132; called by muse, mutect2, varscan2
- CSTF2T | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV58656767; called by mutect2, varscan2
- KCNH8 | c.1828A>C p.K610Q | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60467627; called by muse, mutect2, varscan2
- KCNN3 | c.1238T>A p.L413Q | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55219561, COSV55228211; called by muse, mutect2, varscan2
- LRBA | c.8563T>C p.W2855R | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1413666580, COSV100840853; called by muse, mutect2
- NCKAP5 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs765148309, COSV58452409; called by muse, mutect2, varscan2
- NPNT | c.841A>T p.T281S | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV59754790; called by muse, varscan2
- PCDHGA5 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.158); catalogued as COSV53971039; called by muse, mutect2, varscan2
- PKHD1L1 | c.11438G>A p.R3813K | Missense Mutation (SNP) | VAF 268/618 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV65745851; called by muse, varscan2
- PRPF8 | c.2059G>C p.A687P | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV59264518; called by muse, mutect2, varscan2
- SNED1 | c.2813T>A p.L938H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV60026278; called by muse, mutect2
- SPG11 | c.23C>G p.A8G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200939573, COSV55997076; called by muse, mutect2
- TAS2R5 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332092827, COSV56095479; called by muse, mutect2
- TPH1 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs41274348; called by muse, varscan2
- ZNF236 | c.3332A>G p.E1111G | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV99468719; called by muse, mutect2
- CACNA1G | c.2997C>T p.S999= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as rs202154530, COSV61729566; called by muse, mutect2, varscan2
- CAD | c.6501C>T p.L2167= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs1482826607, COSV53028288; called by muse, mutect2, varscan2
- DDX11 | c.1275C>T p.Y425= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as rs1251824258, COSV52506114; called by muse, mutect2, varscan2
- FAT2 | c.456G>A p.S152= | Silent (SNP) | VAF 14/185 reads (8%) | catalogued as rs372447089; called by muse, mutect2
- KRT19 | c.573T>C p.D191= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as COSV54180036; called by muse, mutect2, varscan2
- MUC16 | c.10938C>T p.S3646= | Silent (SNP) | VAF 77/212 reads (36%) | catalogued as COSV67474987; called by muse, mutect2, varscan2
- PPWD1 | c.1272T>G p.S424= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs780334568, COSV54334162; called by muse, mutect2, varscan2
